FM case AD7225 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/d15cadb4-6683-43cc-b30a-2baf318c04e1

Female, 63.2 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the ovary; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
